Somatic mutation profile of cancer-model specimen HCM-CSHL-0607-C19-85A (3D Organoid, passage 5; aliquot HCM-CSHL-0607-C19-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0607-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 75.4 years (27,554 days).
Specimen HCM-CSHL-0607-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e08f92a-179b-4596-ac6b-720f402b8c15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0607-C19-10B (Blood Derived Normal), aliquot HCM-CSHL-0607-C19-10B-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12eb0420-0661-4363-97cf-318c7fa3c66a

The open-access MAF lists 199 somatic variants for this specimen: 141 protein-altering or splice-affecting, 50 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 50, Nonsense Mutation 6, Frame Shift Ins 5, Intron 3, Frame Shift Del 3, 5'Flank 2, Splice Site 2, Splice Region 1, 3'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 28/435 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- SCN3A | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 111/501 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs774195502, CM140384, COSV51800839; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 219/219 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5320G>A p.E1774K | Missense Mutation (SNP) | VAF 263/384 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs145071620, CM1512521; called by muse, mutect2, varscan2
- ABCA9 | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 183/414 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs375389452; called by muse, mutect2, varscan2
- ACVR1C | c.799T>A p.W267R | Missense Mutation (SNP) | VAF 15/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54651601; called by muse, mutect2
- AGPAT4 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs781252538, COSV57248906; called by muse, mutect2
- AKAP3 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 164/381 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as rs1309107057; called by muse, mutect2, varscan2
- ANKRD24 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 574/885 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as rs774871512, COSV53667923; called by muse, mutect2, varscan2
- ANPEP | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 107/400 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs201577768; called by muse, mutect2, varscan2
- APC | c.3842C>A p.S1281* | Nonsense Mutation (SNP) | VAF 140/140 reads (100%) | catalogued as CM106371, COSV57326196, COSV57330499; called by muse, mutect2, varscan2
- BNC2 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 130/524 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1346486985, COSV66143090; called by muse, mutect2, varscan2
- BRCA2 | c.6613G>T p.V2205L | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101203808; called by muse, mutect2, varscan2
- BRCA2 | c.6614T>G p.V2205G | Missense Mutation (SNP) | VAF 97/213 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs730881546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 313/480 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1225570532, COSV56522636; called by muse, varscan2
- CACNA1C | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 208/475 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250247511, COSV100216250, COSV59747648; called by muse, mutect2, varscan2
- CACNA1I | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 177/650 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs61607492, COSV100361656; called by muse, mutect2, varscan2
- CALN1 | c.136C>T p.R46W (on ENST00000329008 / NM_001017440.3; = p.R88W on NM_031468.4) | Missense Mutation (SNP) | VAF 335/473 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61119319; called by muse, mutect2, varscan2
- CD244 | c.413G>A p.R138H (on ENST00000368033 / NM_001166663.2; = p.R133H on NM_016382.4) | Missense Mutation (SNP) | VAF 273/436 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755036224; called by muse, mutect2, varscan2
- CD300C | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 325/629 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.192); catalogued as rs143534670, COSV58170450; called by muse, mutect2, varscan2
- CDH15 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 300/499 reads (60%) | SIFT tolerated (0.89); PolyPhen benign (0.039); catalogued as rs369126978, COSV57025415, COSV99229015; called by muse, mutect2, varscan2
- CEP89 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 142/499 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768932479, COSV59864189; called by muse, mutect2, varscan2
- COL25A1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 303/479 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV67659445; called by muse, mutect2, varscan2
- CORIN | c.2845A>G p.I949V | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV99904370; called by muse, mutect2, varscan2
- CRISPLD2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs199608437, COSV52282578; called by muse, mutect2, varscan2
- CRTAC1 | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 231/539 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs777292975; called by mutect2, varscan2
- DNAH5 | c.1539C>T p.G513= | Splice Region (SNP) | VAF 65/161 reads (40%) | catalogued as rs778297786; called by muse, mutect2, varscan2
- DPYSL4 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58307134; called by muse, mutect2, varscan2
- DSCAM | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 238/240 reads (99%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as rs774341674, COSV68020548; called by muse, mutect2, varscan2
- DUSP10 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1303727139, COSV60457539; called by muse, mutect2, varscan2
- EPGN | c.377T>A p.L126H | Missense Mutation (SNP) | VAF 145/228 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs766515617; called by muse, mutect2, varscan2
- EPHB1 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 149/246 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs149160192; called by muse, mutect2, varscan2
- FNDC1 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 26/787 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV51949436; called by muse, mutect2
- FOXG1 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 470/736 reads (64%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.503); catalogued as COSV57395986; called by muse, mutect2, varscan2
- GABRD | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 247/247 reads (100%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1194802055, COSV66081908; called by muse, mutect2, varscan2
- GGT6 | c.733G>A p.A245T (on ENST00000574154 / NM_001122890.3; = p.A213T on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 467/468 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.129); catalogued as rs374048557; called by muse, mutect2, varscan2
- HOXD12 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 510/1040 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1216506512, COSV101184276; called by muse, mutect2, varscan2
- HTR1A | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 447/448 reads (100%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1561279015, COSV60503047; called by muse, mutect2, varscan2
- ITGA9 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.204); catalogued as rs1290758183, COSV53246712; called by muse, mutect2, varscan2
- KCNK18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 211/491 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs777473803, COSV57971130; called by muse, mutect2, varscan2
- KRTAP4-6 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 680/1738 reads (39%) | SIFT tolerated (0.13); catalogued as rs776045940, COSV61982167; called by muse, mutect2, varscan2
- LRFN3 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 244/733 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs771862544; called by muse, varscan2
- MUC16 | c.30854C>T p.A10285V | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as rs1163347785; called by muse, mutect2
- NLRP13 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 316/491 reads (64%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as rs372299456; called by muse, mutect2
- NLRP4 | c.2912C>T p.T971M | Missense Mutation (SNP) | VAF 96/312 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs374023533; called by muse, mutect2, varscan2
- NPAP1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 629/630 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1397820294, COSV61508092; called by muse, mutect2, varscan2
- NRP1 | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 129/345 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.752); catalogued as rs750320738, COSV55160209; called by muse, mutect2, varscan2
- NUFIP1 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 94/488 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1160678113; called by muse, mutect2, varscan2
- NUTM2E | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 167/598 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1158957617; called by muse, mutect2, varscan2
- OBSL1 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 514/1037 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs751624583, COSV54704816; called by muse, varscan2
- OPLAH | c.851G>C p.S284T | Missense Mutation (SNP) | VAF 558/1086 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782542003; called by muse, mutect2, varscan2
- OR11H12 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 172/576 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545400527; called by muse, varscan2
- OR8I2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 251/400 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs749476782, COSV56166494, COSV56170718; called by muse, mutect2, varscan2
- PCDH19 | c.3046G>A p.A1016T (on ENST00000373034 / NM_001184880.2; = p.A968T on NM_020766.3) | Missense Mutation (SNP) | VAF 491/491 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV55257182; called by muse, mutect2, varscan2
- PCDHGC5 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755163825, COSV52758777; called by muse, mutect2, varscan2
- POU6F2 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 400/578 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs764707260; called by muse, mutect2
- PPP1R16B | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 332/767 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs769833387; called by muse, mutect2, varscan2
- PXDNL | c.2948C>T p.T983M | Missense Mutation (SNP) | VAF 372/787 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV62476316; called by muse, mutect2, varscan2
- RBM28 | c.1286C>T p.T429M | Missense Mutation (SNP) | VAF 51/789 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs188134024; called by muse, mutect2
- RELN | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 261/374 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs540271067, COSV59026558; called by muse, mutect2, varscan2
- RUNX2 | c.980C>A p.T327N | Missense Mutation (SNP) | VAF 103/479 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV61845573; called by muse, mutect2, varscan2
- SCEL | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs900377283; called by muse, mutect2, varscan2
- SHISAL1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 42/820 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs757448925, COSV66987684, COSV66987790; called by muse, mutect2
- SLC27A6 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs368771261, COSV52480398; called by muse, mutect2, varscan2
- SLC4A1 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 114/453 reads (25%) | catalogued as rs757158425; called by muse, mutect2, varscan2
- SOX11 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 261/527 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58988296; called by muse, mutect2, varscan2
- SPAM1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371105891; called by muse, mutect2, varscan2
- STON1 | c.1964T>G p.L655* | Nonsense Mutation (SNP) | VAF 21/490 reads (4%) | catalogued as rs1025321051; called by muse, mutect2
- TLN1 | c.6625C>T p.R2209C | Missense Mutation (SNP) | VAF 197/580 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1297371769, COSV100147211; called by muse, mutect2, varscan2
- TNIP2 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145123249, COSV100198614; called by muse, mutect2
- TRAV6 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1262183172; called by muse, mutect2, varscan2
- UNC80 | c.6530C>T p.P2177L | Missense Mutation (SNP) | VAF 48/810 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1229965053; called by muse, mutect2
- UNC80 | c.6797G>A p.R2266Q | Missense Mutation (SNP) | VAF 260/534 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55897955; called by muse, mutect2, varscan2
- ZNF28 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 187/310 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1050390526; called by muse, mutect2, varscan2
- ZP4 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV63912760; called by muse, mutect2
- ABCA9 | c.3658C>A p.L1220M | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC073111.3 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 311/1184 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADAM33 | c.1340A>C p.H447P | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- AHR | c.479A>C p.E160A | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKRD66 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 20/532 reads (4%) | called by muse, mutect2
- ASB2 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 640/967 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BARD1 | c.1164T>G p.I388M | Missense Mutation (SNP) | VAF 309/600 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BCL9 | c.3416dup p.F1141Lfs*62 | Frame Shift Ins (INS) | VAF 324/869 reads (37%) | called by pindel, varscan2*
- C11orf24 | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 370/579 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CACNA1B | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CAMSAP2 | c.3642A>T p.K1214N (on ENST00000236925 / NM_001297707.2; = p.K1203N on NM_203459.3) | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CAPRIN2 | c.1342A>T p.K448* | Nonsense Mutation (SNP) | VAF 145/342 reads (42%) | called by muse, mutect2, varscan2
- CD300LD | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 121/540 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CDX4 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 481/482 reads (100%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEACAM5 | c.1422_1423dup p.Y475Sfs*63 | Frame Shift Ins (INS) | VAF 133/541 reads (25%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL6A3 | c.6107G>T p.C2036F | Missense Mutation (SNP) | VAF 30/740 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPED1 | c.850T>A p.L284M | Missense Mutation (SNP) | VAF 428/589 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUBN | c.2361T>G p.I787M | Missense Mutation (SNP) | VAF 24/369 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.301); called by muse, mutect2
- DRAM2 | c.212T>G p.I71S | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- EGFR | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 134/622 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2
- ENPP6 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 137/218 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- FCRLA | c.1067T>A p.V356D (on ENST00000367959; = p.V333D on NM_032738.4) | Missense Mutation (SNP) | VAF 35/531 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- FMO1 | c.954_955insA p.E319Rfs*5 | Frame Shift Ins (INS) | VAF 246/408 reads (60%) | called by mutect2, pindel*, varscan2*
- FRRS1L | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 120/399 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAS2L1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 174/851 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPHN | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 163/266 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KCNN2 | c.896G>C p.R299P (on ENST00000264773; = p.R511P on NM_021614.4) | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KDM5A | c.3059del p.L1020Wfs*28 | Frame Shift Del (DEL) | VAF 31/379 reads (8%) | called by mutect2, pindel*
- KRT36 | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 274/420 reads (65%) | SIFT tolerated (0.68); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LMAN1L | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP5 | c.3733G>T p.V1245L | Missense Mutation (SNP) | VAF 270/425 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MALL | c.168A>T p.Q56H | Missense Mutation (SNP) | VAF 28/969 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- MAP3K10 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 561/838 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- METTL2B | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSH3 | c.413A>T p.K138I | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MTMR7 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECAP1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 174/302 reads (58%) | called by muse, mutect2, varscan2
- NOL4 | c.1057-6_1089del p.X353_splice | Splice Site (DEL) | VAF 132/173 reads (76%) | called by mutect2, pindel, varscan2
- NUDT10 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 87/599 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP188 | c.3295G>C p.E1099Q | Missense Mutation (SNP) | VAF 46/792 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR11H2 | c.709G>T p.G237W (on ENST00000556246; = p.G248W on NM_001197287.1) | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR2Y1 | c.184T>G p.F62V | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PHC2 | c.2387T>A p.V796E (on ENST00000257118 / NM_198040.2; = p.V261E on NM_004427.4) | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRZ1 | c.2126A>T p.E709V | Missense Mutation (SNP) | VAF 28/714 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); called by muse, mutect2
- RELN | c.7792T>C p.Y2598H | Missense Mutation (SNP) | VAF 20/682 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2
- RIBC1 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 426/426 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RNF123 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 171/273 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.9691del p.M3231Cfs*38 | Frame Shift Del (DEL) | VAF 129/415 reads (31%) | called by mutect2, pindel, varscan2
- SCN8A | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 169/463 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC9C2 | c.2534A>G p.K845R | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMAD2 | c.998-6_998del p.X333_splice | Splice Site (DEL) | VAF 140/148 reads (95%) | called by mutect2, pindel, varscan2
- SMG7 | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 253/398 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTBN1 | c.907dup p.M303Nfs*3 | Frame Shift Ins (INS) | VAF 173/441 reads (39%) | called by mutect2, pindel, varscan2
- SUPT6H | c.2503dup p.T835Nfs*9 | Frame Shift Ins (INS) | VAF 91/356 reads (26%) | called by mutect2, pindel, varscan2
- SUSD4 | c.235T>G p.S79A | Missense Mutation (SNP) | VAF 44/650 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2
- TEX14 | c.2744C>A p.S915Y (on ENST00000240361 / NM_001201457.2; = p.S909Y on NM_031272.5) | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TEX51 | c.146G>A p.S49N (on ENST00000643416; = p.X49_splice on NM_001322244.2) | Missense Mutation (SNP) | VAF 177/710 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TIPARP | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 178/319 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- TJP1 | c.5117A>C p.K1706T | Missense Mutation (SNP) | VAF 19/611 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNFRSF10B | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.062); called by muse, mutect2
- TOR1AIP2 | c.925_974del p.K309Lfs*6 | Frame Shift Del (DEL) | VAF 95/474 reads (20%) | called by mutect2, pindel
- TTLL2 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 20/584 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2
- TTN | c.23714C>T p.T7905I (on ENST00000591111; = p.T6978I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/540 reads (6%) | PolyPhen possibly damaging (0.823); called by muse, mutect2
- ZNF574 | c.1827T>G p.C609W | Missense Mutation (SNP) | VAF 20/769 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- ZNF585B | c.1097G>C p.R366T | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AC073610.2 | c.483A>G p.S161= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as rs778443645; called by muse, mutect2
- ACTR2 | c.294T>C p.L98= | Silent (SNP) | VAF 189/359 reads (53%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.135C>T p.P45= | Silent (SNP) | VAF 105/319 reads (33%) | catalogued as COSV101239735, COSV67130405; called by muse, mutect2, varscan2
- AL358113.1 | c.3909C>T p.S1303= | Silent (SNP) | VAF 104/684 reads (15%) | called by muse, mutect2, varscan2
- APOB | c.5163C>T p.V1721= | Silent (SNP) | VAF 54/740 reads (7%) | catalogued as rs536182427, COSV51925317; called by muse, mutect2
- BHMT2 | c.462C>T p.H154= | Silent (SNP) | VAF 154/155 reads (99%) | catalogued as rs766585032; called by muse, mutect2, varscan2
- BRD1 | c.2910C>T p.D970= (on ENST00000216267 / NM_001349940.1; = p.D1101= on NM_001304808.3) | Silent (SNP) | VAF 153/496 reads (31%) | catalogued as rs747768983; called by muse, mutect2, varscan2
- BUD13 | c.864T>C p.G288= | Silent (SNP) | VAF 264/443 reads (60%) | called by muse, mutect2, varscan2
- C11orf68 | c.591T>C p.I197= (on ENST00000530188; = p.I238= on NM_031450.4) | Silent (SNP) | VAF 68/680 reads (10%) | called by muse, mutect2
- CABLES2 | c.48C>T p.P16= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as rs1287188416; called by muse, mutect2, varscan2
- CHST2 | c.129G>A p.A43= | Silent (SNP) | VAF 196/573 reads (34%) | called by muse, varscan2
- COL4A5 | c.3765G>A p.G1255= | Silent (SNP) | VAF 241/241 reads (100%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.1074A>G p.Q358= | Silent (SNP) | VAF 61/337 reads (18%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.864G>A p.L288= | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- CYP4F8 | c.219C>A p.G73= | Silent (SNP) | VAF 25/507 reads (5%) | called by muse, mutect2
- DNAAF6 | c.345A>T p.I115= | Silent (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2
- DNER | c.1443G>A p.T481= | Silent (SNP) | VAF 228/520 reads (44%) | catalogued as rs144811178; called by muse, mutect2, varscan2
- ERICH1 | c.1194G>T p.L398= | Silent (SNP) | VAF 372/372 reads (100%) | called by muse, mutect2, varscan2
- FAM47B | c.75G>A p.P25= | Silent (SNP) | VAF 432/435 reads (99%) | called by muse, mutect2, varscan2
- FLG | c.6426G>A p.P2142= | Silent (SNP) | VAF 289/457 reads (63%) | catalogued as rs573959413, COSV64240432; called by muse, mutect2, varscan2
- FOXI2 | c.324G>A p.S108= | Silent (SNP) | VAF 321/781 reads (41%) | called by muse, mutect2, varscan2
- GALNT9 | c.1362G>A p.P454= (on ENST00000328957 / NM_001122636.2; = p.P88= on NM_021808.3) | Silent (SNP) | VAF 274/524 reads (52%) | catalogued as rs377144604; called by muse, mutect2, varscan2
- HRNR | c.1686G>C p.G562= | Silent (SNP) | VAF 60/696 reads (9%) | called by muse, mutect2
- INPP4A | c.366C>T p.V122= | Silent (SNP) | VAF 106/293 reads (36%) | catalogued as COSV50834114, COSV99304897; called by muse, mutect2, varscan2
- LRRC74A | c.1056G>T p.L352= | Silent (SNP) | VAF 109/178 reads (61%) | called by muse, mutect2, varscan2
- MYF6 | c.150G>A p.P50= | Silent (SNP) | VAF 348/609 reads (57%) | catalogued as rs556819653, COSV57350812; called by muse, mutect2, varscan2
- NEK1 | c.1818A>G p.E606= | Silent (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2, varscan2
- NFATC2 | c.2220C>T p.A740= | Silent (SNP) | VAF 469/924 reads (51%) | called by muse, varscan2
- NKX2-1 | c.435G>C p.S145= | Silent (SNP) | VAF 508/741 reads (69%) | called by muse, mutect2, varscan2
- NLRP3 | c.2029C>T p.L677= | Silent (SNP) | VAF 22/420 reads (5%) | called by muse, mutect2
- PEG3 | c.2034T>G p.T678= | Silent (SNP) | VAF 31/471 reads (7%) | catalogued as COSV55642079, COSV99690435; called by muse, mutect2
- PI4KA | c.5793C>T p.A1931= | Silent (SNP) | VAF 85/298 reads (29%) | called by muse, mutect2, varscan2
- PPP4R3C | c.96C>T p.D32= | Silent (SNP) | VAF 244/245 reads (100%) | catalogued as rs978841997; called by muse, mutect2, varscan2
- PSMB1 | c.87A>T p.R29= | Silent (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- RASA4 | c.306C>T p.S102= | Silent (SNP) | VAF 351/958 reads (37%) | catalogued as rs140941587, COSV53548801; called by muse, varscan2
- RASAL3 | c.123C>G p.G41= | Silent (SNP) | VAF 228/700 reads (33%) | called by muse, mutect2, varscan2
- RNF40 | c.1074C>T p.A358= | Silent (SNP) | VAF 125/336 reads (37%) | catalogued as rs368724386, COSV100222325; called by muse, mutect2, varscan2
- SCN9A | c.2712G>A p.T904= (on ENST00000303354; = p.T893= on NM_002977.3) | Silent (SNP) | VAF 38/696 reads (5%) | catalogued as rs200494981; ClinVar: likely benign; called by muse, mutect2
- SCRG1 | c.186G>A p.G62= | Silent (SNP) | VAF 173/276 reads (63%) | called by muse, mutect2, varscan2
- SLC26A8 | c.2115G>A p.G705= | Silent (SNP) | VAF 365/379 reads (96%) | called by muse, mutect2, varscan2
- SLC9C2 | c.1281G>A p.Q427= | Silent (SNP) | VAF 84/165 reads (51%) | called by muse, mutect2, varscan2
- SPARCL1 | c.1224G>A p.K408= | Silent (SNP) | VAF 72/258 reads (28%) | catalogued as rs1398158766; called by muse, mutect2, varscan2
- TBX5 | c.438G>A p.A146= | Silent (SNP) | VAF 37/691 reads (5%) | catalogued as COSV59858890; called by muse, mutect2
- THSD7A | c.4263T>G p.S1421= | Silent (SNP) | VAF 34/486 reads (7%) | called by muse, mutect2
- TMEM178A | c.252C>T p.R84= | Silent (SNP) | VAF 40/898 reads (4%) | catalogued as COSV56141651; called by muse, mutect2
- TMTC4 | c.1620T>A p.S540= (on ENST00000376234 / NM_001350577.2; = p.S559= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 93/399 reads (23%) | called by muse, mutect2, varscan2
- TP53I11 | c.270G>A p.A90= | Silent (SNP) | VAF 315/541 reads (58%) | catalogued as rs376698519; called by muse, mutect2, varscan2
- TRPC3 | c.651C>T p.D217= (on ENST00000379645 / NM_001366479.2; = p.D144= on NM_003305.2) | Silent (SNP) | VAF 125/340 reads (37%) | catalogued as rs769632483, COSV53378671, COSV53383696; called by muse, mutect2, varscan2
- WIZ | c.1882C>T p.L628= | Silent (SNP) | VAF 400/646 reads (62%) | catalogued as rs1264068472; called by muse, mutect2
- ZNF85 | c.210C>T p.I70= | Silent (SNP) | VAF 164/237 reads (69%) | catalogued as rs1396903935; called by muse, mutect2, varscan2
- EML2 | chr19:45642186 C>T | 5'Flank (SNP) | VAF 525/761 reads (69%) | catalogued as rs1289540933; called by muse, mutect2, varscan2
- FAM131A | chr3:184337712 C>T | 5'Flank (SNP) | VAF 228/356 reads (64%) | catalogued as rs1355363594; called by muse, mutect2, varscan2
- KLHL1 | c.-268C>T | 5'UTR (SNP) | VAF 264/593 reads (45%) | called by muse, mutect2, varscan2
- OR5R1 | chr11:56413257 C>T | 3'Flank (SNP) | VAF 32/362 reads (9%) | catalogued as rs972890565; called by muse, mutect2
- TTN | c.34522+483G>C | Intron (SNP) | VAF 32/616 reads (5%) | called by muse, mutect2
- YY1AP1 | c.48-48C>T | Intron (SNP) | VAF 437/652 reads (67%) | catalogued as rs1374981890; called by muse, mutect2, varscan2
- ZNF812P | n.584T>A | RNA (SNP) | VAF 207/329 reads (63%) | called by muse, mutect2, varscan2
- ZNF816 | c.190+12G>A | Intron (SNP) | VAF 112/435 reads (26%) | called by muse, mutect2, varscan2
